Somatic mutation profile of tumor specimen 0DQ2NC from CCDI case PBCEJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,960 days).
Specimen 0DQ2NC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f552bd3b-49d3-40d8-856d-a43213a84ef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2OY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0a482d-0116-470c-b67b-ee2b3ba4ce50

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4025G>A p.R1342K | Missense Mutation (SNP) | VAF 189/604 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV54347871; called by muse, mutect2, varscan2
- XIRP2 | c.718G>A p.V240I (on ENST00000628543; = p.V415I on NM_152381.6) | Missense Mutation (SNP) | VAF 78/1118 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs753964672; called by muse, mutect2
- ZNF425 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 153/529 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs749709957, COSV65200831; called by muse, mutect2, varscan2
- SI | c.3239G>T p.S1080I | Missense Mutation (SNP) | VAF 175/639 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TMA16 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 258/820 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TPO | c.2618+1G>A p.X873_splice | Splice Site (SNP) | VAF 114/389 reads (29%) | called by muse, mutect2, varscan2
